Gene-level copy-number profile of tumor specimen TCGA-44-5643-01A from TCGA case TCGA-44-5643, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 53.2 years (19,426 days).
Specimen TCGA-44-5643-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.56b05714-3de6-40b4-b2fd-11a38878d01d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-5643-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d23707b1-6284-48f4-8bab-32a86676b682

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 29,903; copy number 2: 27,745; copy number 3: 684; copy number 4: 4; copy number 5: 549; copy number 6: 912.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-5643-01A-01D-1624-01): tumor purity 0.56, ploidy 1.63, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:114,445,521–114,687,609, 2 genes: ZBTB20-AS5, ZBTB20-AS2.
- chr4:179,923,773–182,145,249, 14 genes (within-gene range 0–1): AC108169.1, AC096747.1, NDUFB5P1, AC104803.1, LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2, AC084741.1, TEMN3-AS1, RN7SKP13, TENM3-AS1, CCNHP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,461 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:167,441,789–198,222,513, 611 genes, copy number 5–6 (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 27,523. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
